Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7478, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7478-01A (Primary Tumor).

Pathology Report

Microscopic Discussion:

1,2 Sections demonstrate a moderately hypercellular glial neoplasm. The tumor is composed predominantly of ordinary gemistocytes and fibrillary astrocytes. A minor population of smaller gemistocytes is seen but definite oligodendroglioma differentiation is not noted. Atypia is moderate to marked but no mitotic figures are identified. There is no microvascular proliferation or necrosis.

Addendum Discussion:

The neoplastic cells are immunoreactive for p53, suggesting astrocytic origin. MIB-1 reactive cells are present throughout the tumor. A labeling index of 6.2% is calculated. This is at the high end of the range expected in a grade II astrocytoma but would be relatively low for a higher grade tumor. Overall, this does not warrant classification of the tumor as anaplastic, but does indicate the need for close observation

Final Addendum Diagnosis:

Well-differentiated astrocytoma (WHO grade II)

Source: NCI Genomic Data Commons file 3f8cd666-47f8-4667-b4df-f5ee79c6bea4 (TCGA-HT-7478.9BE4B6B7-F32A-413D-ADB9-3CA98802E71B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).